Surgical pathology report (de-identified scan), TCGA case TCGA-DD-A39V, project TCGA-LIHC (Liver Hepatocellular Carcinoma), tissue source site Mayo Clinic - Rochester, specimen TCGA-DD-A39V-01A (Primary Tumor).

Patient Key:

Surgical date:

TISSUE DESCRIPTION:

Right lobe liver (1045 grams, 20 x 17 x 7.5 cm) and gallbladder (10 x 4 x 3 cm).

A1, B1, B2, B3, B4, B5, B6, B7, B8, B9, B10, B11

DIAGNOSIS:

Liver, right lobe, resection: Grade 3 (of 4) hepatocellular carcinoma, usual type forming a dominant 4.6 x 4.3 x 3.2 cm mass with a single satellite nodule measuring 0.4 cm in greatest dimension. The tumor is located in the right lobe. The hepatic capsule is free of tumor. The surgical margins are free of tumor. Extramural vascular invasion is not identified. The tumor is not encapsulated, infiltration of parenchyma being of the pushing type. The non-neoplastic liver will be reported in an addendum.

Gallbladder, cholecystectomy: Mild chronic cholecystitis.

ADDENDUM:

The non-neoplastic liver shows mild tumor effect. No evidence of chronic or primary liver disease.

ICD-0-3
carcinoma, hepatocellular, NOS 8170/3
Site: liver C22.0
hw
4/22/11

IIA Discrepancy		☒

Source: NCI Genomic Data Commons file 93927d42-0a4d-4f51-b331-8cccf907bb98 (TCGA-DD-A39V.AB7EF7A1-F8F1-404A-BF15-2CC53F63C033.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).